Surgical pathology report (de-identified scan), TCGA case TCGA-P8-A5KD, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site University of Pittsburgh, specimen TCGA-P8-A5KD-01A (Primary Tumor).

ICD-O-3
Pheochromocytoma NOS
8700/3
Site Adrenal gland NOS
C74.9
9/23/28/13

Collection Date:

FINAL DIAGNOSIS:

ADRENAL GLAND, RIGHT, ADENALECTOMY (57 GRAMS) -

- A. PHEOCHROMOCYTOMA (5.0 CM), CONFINED TO ADRENAL GLAND.
- B. TUMOR CLUSTERS IN VESSELS (see comment).
- C. ADRENAL CORTEX WITH NO SIGNIFICANT ABNORMALITIES.

COMMENT:

Though there are tumor clusters in vessels, other features predictive of malignancy are not evident. Specifically, mitotic counts are less 1 per 10 high power fields, there is no necrosis, capsular invasion, or profound atypia/solid growth.

Also, only metastasis is regarded as a defining criterion for a 'malignant pheochromocytoma.'

Diagnosis Inconsistency		/
Metastatic Site Discrepancy		/
Primary Malignancy history		/
Qual. Synchronous Primary Tumor		/

Source: NCI Genomic Data Commons file b8053d1c-6dd9-40e9-8b2d-a944305ea147 (TCGA-P8-A5KD.D4C6C0AC-0252-42FA-8531-3E42CD336C72.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).